Somatic mutation profile of tumor specimen TARGET-30-PAIXNV-01A (aliquot TARGET-30-PAIXNV-01A-01W) from TARGET case TARGET-30-PAIXNV, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Age at diagnosis: 1.8 years (644 days).
Specimen TARGET-30-PAIXNV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 471eeb30-7fa0-4d5c-834c-c4c53b96b663.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAIXNV-10A (Blood Derived Normal), aliquot TARGET-30-PAIXNV-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4cbf723-91d0-4824-921f-15d11dc66619

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AVPR1A | c.509T>C p.M170T | Missense Mutation (SNP) | VAF 38/260 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV54547082; called by muse, mutect2, varscan2
- DIP2B | c.3629G>C p.W1210S | Missense Mutation (SNP) | VAF 37/341 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.974); catalogued as COSV56586390, COSV99999646; called by muse, mutect2, varscan2
- OR2Z1 | c.474C>G p.I158M | Missense Mutation (SNP) | VAF 47/456 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.297); catalogued as rs1187804965, COSV60691730, COSV60692713; called by muse, mutect2, varscan2
- PAX5 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.239); catalogued as COSV63908833; called by muse, mutect2, varscan2
- TMEM86A | c.521G>T p.W174L | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55011068; called by muse, mutect2, varscan2
- TRIOBP | c.3361C>T p.R1121W | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs200686409; called by muse, mutect2, varscan2
- CC2D2B | c.592T>C p.C198R | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2
- CNTN5 | c.1514C>A p.P505H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DNAH11 | c.2532G>C p.W844C | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2
- EDEM3 | c.2638T>A p.C880S | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.025); called by muse, mutect2
- HYAL4 | c.664G>T p.D222Y | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- FHDC1 | c.1245G>A p.L415= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as rs1280168755, COSV52600850; called by muse, mutect2, varscan2
- KMT2B | c.5556C>T p.A1852= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs946230696, COSV55863536; called by muse, mutect2
- SLC22A23 | c.1485G>A p.G495= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV66678133; called by muse, mutect2
- DENND10P1 | n.1239G>C | RNA (SNP) | VAF 28/440 reads (6%) | called by muse, mutect2
- RPL4 | c.175+73C>A | Intron (SNP) | VAF 34/392 reads (9%) | called by muse, mutect2
